Gene-level copy-number profile of tumor specimen TCGA-BR-4357-01A from TCGA case TCGA-BR-4357, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G2; Age at diagnosis: 58.3 years (21,295 days).
Specimen TCGA-BR-4357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4008290f-3dfd-4acb-87c9-1590c29c51db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4357-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 859 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b23cd6b2-2aab-4f4a-814b-c1d80e71532e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,951; copy number 2: 36,758; copy number 3: 15,330; copy number 4: 3,330; copy number 5: 1,501; copy number 6: 264; copy number 7: 190; copy number 8: 281; copy number 9: 12; copy number 10: 36; copy number 11: 56; copy number 15: 8; copy number 16: 11; copy number 17: 1; copy number 18: 8; copy number 25: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4357-01A-01D-1155-01): tumor purity 0.44, ploidy 2.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:13,000,953–14,992,066, 10 genes (within-gene range 0–2): AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1.
- chr6:1,623,806–2,245,605, 1 gene (within-gene range 0–2): GMDS.
- chr6:48,701,491–48,952,781, 3 genes: FO393412.1, AL391538.1, AL022099.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,381 genes in 80 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,159,430–6,701,924, 25 genes, copy number 6: AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11.
- chr1:9,182,004–11,102,100, 61 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr1:15,941,869–16,241,398, 21 genes, copy number 8: ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, AL109627.1, CPLANE2, MT1XP1.
- chr1:19,664,875–23,696,835, 122 genes, copy number 6–11 (broad region; genes not listed).
- chr1:150,363,091–150,876,708, 24 genes, copy number 5 (within-gene range 3–5): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P.
- chr1:151,629,324–152,196,699, 36 genes, copy number 5: RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:207,088,860–207,641,765, 13 genes, copy number 5: C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, AL391597.1, CR2, CR1, AL137789.1.
- chr1:225,401,502–226,333,655, 31 genes, copy number 5–8: LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1.
- chr1:234,709,383–235,161,283, 15 genes, copy number 5–15: AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr2:157,725,708–158,236,169, 11 genes, copy number 6: AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1.
- chr3:132,645,831–134,250,859, 29 genes, copy number 5 (within-gene range 3–5): HSPA8P19, UBA5, NPHP3, NPHP3-AS1, AC079942.1, TMEM108, TMEM108-AS1, BFSP2, AC055753.1, BFSP2-AS1, AC022296.2, AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140, TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14.
- chr3:193,398,967–194,250,203, 21 genes, copy number 7 (within-gene range 3–7): ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036.
- chr6:154,154,496–154,834,244, 13 genes, copy number 5 (within-gene range 3–5): IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P.
- chr7:130,645,225–131,497,694, 21 genes, copy number 5: AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2.
- chr7:141,862,860–142,345,985, 21 genes, copy number 5: OR9A3P, OR9A1P, MGAM, OR9N1P, OR9A4, CLEC5A, TAS2R38, MGAM2, MOXD2P, PRSS58, TRY2P, AC245088.1, PRSS3P3, TRBV1, TRBV2, TRBV3-1, TRBV4-1, TRBV5-1, TRBV6-1, TRBV7-1, TRBV4-2.
- chr7:156,872,078–157,282,686, 14 genes, copy number 5: RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2.
- chr8:80,484,561–81,924,348, 46 genes, copy number 5: AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:97,132,835–103,501,895, 163 genes, copy number 5 (broad region; genes not listed).
- chr8:116,766,505–127,742,951, 170 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:132,866,958–133,571,940, 13 genes, copy number 5 (within-gene range 4–5): TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:139,096,305–140,458,579, 11 genes, copy number 5 (within-gene range 3–5): AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13.
- chr8:141,507,333–142,812,120, 32 genes, copy number 5: AC138647.2, AC138647.1, AC025839.1, MIR1302-7, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4.
- chr9:2,421,597–5,629,748, 63 genes, copy number 5 (broad region; genes not listed).
- chr11:34,430,880–35,585,310, 21 genes, copy number 7–18: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1.
- chr11:71,998,613–74,669,117, 104 genes, copy number 5–10 (broad region; genes not listed).
- chr13:27,162,855–27,488,232, 14 genes, copy number 5: USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P.
- chr14:75,013,769–75,546,993, 19 genes, copy number 5–8: MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF.
- chr15:89,784,895–90,138,016, 18 genes, copy number 5: ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT.
- chr16:9,753,404–19,706,793, 270 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr16:28,341,437–28,740,781, 26 genes, copy number 8 (within-gene range 2–8): AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27, NUPR1, AC020765.6, AC020765.1, AC020765.2, SGF29, SULT1A2, AC020765.3, AC020765.4, SULT1A1, AC020765.5, NPIPB8, AC145285.4, EIF3C.
- chr16:84,817,182–85,149,443, 10 genes, copy number 5: AC025280.3, CRISPLD2, AC025280.1, AC025280.2, LINC02176, ZDHHC7, KIAA0513, CIBAR2, LINC02139, AC026469.1.
- chr17:39,546,104–39,747,291, 13 genes, copy number 25: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:45,190,931–45,490,749, 14 genes, copy number 10 (within-gene range 3–10): AC008105.3, FMNL1, AC008105.1, AC008105.2, MAP3K14-AS1, SPATA32, MAP3K14, RNA5SP443, AC003070.2, ARHGAP27, AC003070.1, PLEKHM1, AC091132.2, MIR4315-1.
- chr17:50,094,737–50,948,750, 55 genes, copy number 5–7 (within-gene range 3–7): PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1, XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3.
- chr17:75,031,097–75,289,510, 22 genes, copy number 8: RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19.
- chr17:76,376,584–76,733,936, 28 genes, copy number 8 (within-gene range 2–8): SPHK1, UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3, METTL23.
- chr19:28,294,093–30,085,893, 47 genes, copy number 7–16: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:17,187,510–17,735,871, 15 genes, copy number 5: RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2.
- chr20:41,402,083–63,969,930, 561 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:37,805,093–38,041,915, 17 genes, copy number 5 (within-gene range 2–5): H1-0, GCAT, GALR3, ANKRD54, MIR658, MIR659, EIF3L, AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534.

Autosomal genes at a single copy (total copy number 1): 890. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
